Gene-level copy-number profile of tumor specimen TCGA-FS-A1ZE-06A from TCGA case TCGA-FS-A1ZE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 41.7 years (15,249 days).
Specimen TCGA-FS-A1ZE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.e4654571-2d63-4e78-8f72-d222fbef98ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1ZE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07d2c4d3-2e0f-4a80-a67a-b7bfc3e2c40e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 8,214; copy number 2: 44,586; copy number 3: 5,079; copy number 4: 1,066; copy number 5: 332; copy number 6: 264; copy number 7: 211; copy number 8: 21; copy number 10: 6; copy number 13: 29; copy number 14: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1ZE-06A-11D-A191-01): tumor purity 0.98, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 866 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,286–2,262,109, 83 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:70,972–5,073,223, 108 genes, copy number 5–7 (broad region; genes not listed).
- chr7:6,022,247–12,243,367, 94 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr7:13,854,355–13,991,425, 3 genes, copy number 5: AC005019.2, AC005019.1, ETV1.
- chr7:15,200,317–15,842,360, 8 genes, copy number 5: AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1.
- chr7:18,892,096–20,140,453, 15 genes, copy number 5: HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1.
- chr7:20,141,916–20,153,531, 1 gene, copy number 5: MACC1-AS1.
- chr7:24,318,094–24,445,128, 1 gene, copy number 5 (within-gene range 2–5): AC003044.1.
- chr7:31,687,215–32,428,131, 3 genes, copy number 5 (within-gene range 2–5): PPP1R17, PDE1C, SNX2P2.
- chr7:34,209,465–35,038,271, 10 genes, copy number 5: AC009262.1, RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N.
- chr20:28,563,850–30,816,274, 32 genes, copy number 7: FRG1CP, FRG1DP, 5_8S_rRNA, DUX4L32, PCMTD1P7, DUX4L33, DUX4L34, FRG2EP, RARRES2P11, AGGF1P10, DUX4L35, FRG1EP, FAM242B, Y_RNA, CFTRP2, 5_8S_rRNA, CDC27P3, RNA5SP532, DUX4L37, CFTRP3, LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1, 5_8S_rRNA, AC018688.1, ANKRD20A21P, U6, RNA5SP528.
- chr20:32,237,795–32,743,567, 15 genes, copy number 7 (within-gene range 1–7): MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1.
- chr20:32,819,954–33,792,269, 34 genes, copy number 7 (within-gene range 4–7): MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2.
- chr20:34,194,569–36,773,818, 97 genes, copy number 6–13 (within-gene range 4–13) (broad region; genes not listed).
- chr20:38,962,299–39,039,723, 1 gene, copy number 7 (within-gene range 1–7): DHX35.
- chr20:39,213,777–40,126,357, 10 genes, copy number 7–14: LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1.
- chr20:41,547,422–42,063,969, 6 genes, copy number 8: RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3.
- chr20:42,606,694–42,607,559, 1 gene, copy number 7: AL035666.1.
- chr20:63,090,806–64,313,132, 80 genes, copy number 6 (broad region; genes not listed).
- chr22:17,777,322–18,894,407, 47 genes, copy number 5: LINC00528, MICAL3, AC016026.1, AC016026.2, MIR648, AC016027.3, AC016027.2, RHEBP3, LINC01634, AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18, FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, FAM246B, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1.
- chr22:20,299,760–21,064,168, 49 genes, copy number 5 (within-gene range 1–5): AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B.
- chr22:40,346,500–45,341,955, 168 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,793. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
